Gene-level copy-number profile of tumor specimen TCGA-AD-6888-01A from TCGA case TCGA-AD-6888, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 73.4 years (26,816 days).
Specimen TCGA-AD-6888-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.ebb499d4-a3d5-4fc8-9297-1eb59ddcef0d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AD-6888-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d5e05d8-2c6c-437f-8c8c-65527b417275

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 269; copy number 2: 3,340; copy number 3: 34,401; copy number 4: 4,312; copy number 5: 10,567; copy number 6: 4,512; copy number 7: 527; copy number 8: 673; copy number 9: 96; copy number 10: 773; copy number 11: 5; copy number 13: 110; copy number 14: 125; copy number 16: 12; copy number 21: 49; copy number 30: 41.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AD-6888-01A-11D-1923-01): tumor purity 0.57, ploidy 3.51, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,377 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:140,282,465–159,233,377, 493 genes, copy number 7 (broad region; genes not listed).
- chr13:56,885,284–114,337,626, 660 genes, copy number 8 (broad region; genes not listed).
- chr17:19,411,125–19,597,922, 13 genes, copy number 8: RNF112, AC004448.3, AC004448.2, LINC02094, AC004448.4, RPS2P46, AC004448.1, SLC47A1, RPL17P43, SNORA59B, AC025627.1, SLC47A1P1, AC025627.2.
- chr17:19,678,288–21,574,517, 96 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr17:36,722,443–40,100,589, 126 genes, copy number 13–30 (broad region; genes not listed).
- chr19:27,638,483–32,485,895, 90 genes, copy number 14 (broad region; genes not listed).
- chr20:30,214,765–64,313,132, 899 genes, copy number 10–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 269. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
